Somatic mutation profile of cancer-model specimen HCM-CSHL-0460-C50-85A (3D Organoid; aliquot HCM-CSHL-0460-C50-85A-01D-A79C-36), derived from the primary tumor of HCMI case HCM-CSHL-0460-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 57.1 years (20,838 days).
Specimen HCM-CSHL-0460-C50-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e54c38b-be8d-4a56-aa57-95be5de53502.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0460-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0460-C50-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8c7d58b-a4e0-451e-9cf4-bb0c5710ec60

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 20, Silent 11, Nonsense Mutation 4, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 50/98 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ADGRV1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 491/990 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.827); catalogued as rs1228352007; called by muse, mutect2, varscan2
- CORO2B | c.1379A>T p.D460V | Missense Mutation (SNP) | VAF 24/558 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV55957346; called by muse, mutect2
- DPP6 | c.1987C>T p.R663C (on ENST00000377770 / NM_001364500.2; = p.R601C on NM_001936.5) | Missense Mutation (SNP) | VAF 449/899 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1443134542, COSV59600522; called by muse, mutect2, varscan2
- KCNC3 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 308/661 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1377387549, COSV65386867; called by muse, mutect2, varscan2
- LAMB1 | c.3446G>A p.G1149D | Missense Mutation (SNP) | VAF 69/496 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779579592; called by muse, mutect2, varscan2
- OGDHL | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 190/450 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs764443387, COSV65101235; called by muse, mutect2, varscan2
- SLC24A1 | c.3176T>C p.I1059T | Missense Mutation (SNP) | VAF 52/337 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775295158; called by muse, mutect2, varscan2
- SYTL4 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 116/284 reads (41%) | catalogued as COSV52169822; called by muse, mutect2, varscan2
- ARHGEF10 | c.2564A>T p.E855V (on ENST00000398564; = p.E830V on NM_014629.4) | Missense Mutation (SNP) | VAF 119/255 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CDH1 | c.670_673del p.R224Lfs*25 | Frame Shift Del (DEL) | VAF 121/128 reads (95%) | called by mutect2, pindel, varscan2
- CLC | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 26/697 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0.359); called by muse, mutect2
- CPSF7 | c.890C>T p.P297L (on ENST00000394888 / NM_001136040.4; = p.P340L on NM_024811.4) | Missense Mutation (SNP) | VAF 234/514 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, varscan2
- CRACD | c.855G>T p.R285S | Missense Mutation (SNP) | VAF 46/750 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- EPCAM | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 30/575 reads (5%) | called by muse, mutect2
- GIPR | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 314/658 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERC1 | c.8639_8654dup p.A2886Qfs*3 | Nonsense Mutation (INS) | VAF 52/235 reads (22%) | called by mutect2, varscan2
- KLHL23 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 132/304 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- M6PR | c.213C>G p.Y71* | Nonsense Mutation (SNP) | VAF 145/350 reads (41%) | called by muse, mutect2, varscan2
- OR9A4 | c.305T>A p.F102Y | Missense Mutation (SNP) | VAF 236/502 reads (47%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHGA7 | c.2128G>A p.V710I | Missense Mutation (SNP) | VAF 287/638 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PIK3R6 | c.884A>T p.Q295L | Missense Mutation (SNP) | VAF 159/338 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERPINA7 | c.1228G>T p.V410L | Missense Mutation (SNP) | VAF 119/302 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- SPON1 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 415/936 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2
- SPON1 | c.104A>T p.D35V | Missense Mutation (SNP) | VAF 415/938 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.137); called by muse, mutect2
- TRPM5 | c.2681T>A p.L894Q | Missense Mutation (SNP) | VAF 330/698 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CAPN11 | c.1362G>A p.R454= | Silent (SNP) | VAF 76/566 reads (13%) | called by muse, mutect2, varscan2
- EIF3G | c.759C>T p.T253= | Silent (SNP) | VAF 63/694 reads (9%) | catalogued as rs144308529; called by muse, mutect2
- HOXA6 | c.225G>T p.G75= | Silent (SNP) | VAF 38/746 reads (5%) | catalogued as rs1268903732; called by muse, mutect2
- LAMB3 | c.2028G>A p.L676= | Silent (SNP) | VAF 206/824 reads (25%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.327C>T p.P109= | Silent (SNP) | VAF 46/652 reads (7%) | catalogued as rs904711080; called by muse, mutect2
- PTPRE | c.1297T>C p.L433= | Silent (SNP) | VAF 148/322 reads (46%) | called by muse, mutect2, varscan2
- RNPEPL1 | c.142C>T p.L48= | Silent (SNP) | VAF 412/867 reads (48%) | called by muse, mutect2, varscan2
- SHROOM3 | c.2247G>A p.S749= | Silent (SNP) | VAF 275/570 reads (48%) | catalogued as COSV56038245; called by muse, mutect2, varscan2
- TBC1D16 | c.1860C>T p.P620= | Silent (SNP) | VAF 407/811 reads (50%) | catalogued as rs376608231; called by muse, mutect2, varscan2
- TES | c.1128C>G p.T376= | Silent (SNP) | VAF 20/513 reads (4%) | called by muse, mutect2
- TP73 | c.129C>A p.G43= | Silent (SNP) | VAF 36/443 reads (8%) | catalogued as COSV100601377; called by muse, mutect2
